Gene-level copy-number profile of specimen HCM-SANG-1337-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1337-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS.
Specimen HCM-SANG-1337-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 36a7275d-7959-44ee-af3b-3b338f25c0b3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1337-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/7d3e81b5-d801-4e48-a127-f5455bd35d18

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 7,558; copy number 3: 37,602; copy number 4: 11,357; copy number 5: 171; copy number 6: 1,367; copy number 7: 2; copy number 8: 854; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 857 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:65,189,995–65,230,861, 3 genes, copy number 7–9: BMS1P12, AL512605.1, AL512605.2.
- chr20:19,212,642–19,722,926, 1 gene, copy number 8 (within-gene range 5–8): SLC24A3.
- chr20:19,693,209–20,056,046, 6 genes, copy number 8 (within-gene range 5–8): AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.
- chr20:31,257,664–52,699,472, 578 genes, copy number 8 (broad region; genes not listed).
- chr20:53,544,615–64,327,972, 269 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
